Somatic mutation profile of tumor specimen TARGET-30-PAUHSJ-01A (aliquot TARGET-30-PAUHSJ-01A-01D) from TARGET case TARGET-30-PAUHSJ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.6 years (933 days).
Specimen TARGET-30-PAUHSJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8b5a354-0d52-4034-a9ee-e860ffe8256f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUHSJ-10A (Blood Derived Normal), aliquot TARGET-30-PAUHSJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/981ac826-2595-4eea-a802-318a464a8cfe

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 7/102 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- DNAH9 | c.11686G>T p.A3896S | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.088); catalogued as COSV52337487, COSV52385994; called by muse, mutect2, varscan2
